Somatic mutation profile of tumor specimen HTMCP-03-06-02337-01A (aliquot HTMCP-03-06-02337-01A-01D-9392) from CGCI case HTMCP-03-06-02337, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 56.3 years (20,550 days).
Specimen HTMCP-03-06-02337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e13dae2f-3236-468b-94dd-dfcbbf78375d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02337-10A (Blood Derived Normal), aliquot HTMCP-03-06-02337-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2de3a52-cff5-4f3d-a7d2-d41f43a29e00

The open-access MAF lists 33 somatic variants for this specimen: 18 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 17, Silent 15, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 37/100 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52114189, COSV52125802, COSV52127728; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/77 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6176C>T p.P2059L | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs201467662; called by muse, mutect2, varscan2
- CHD6 | c.5224G>T p.D1742Y | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV64692071, COSV64694611; called by muse, mutect2, varscan2
- KLHL4 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64140372; called by muse, mutect2, varscan2
- MAP3K7 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs746282865; called by muse, mutect2, varscan2
- NES | c.2339dup p.E781Rfs*12 | Frame Shift Ins (INS) | VAF 12/137 reads (9%) | catalogued as rs1370581637; called by mutect2, pindel
- SMARCA4 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs751542188, COSV60798215; ClinVar: uncertain significance; called by mutect2, varscan2
- TEX15 | c.6196G>A p.V2066I (on ENST00000256246; = p.V2449I on NM_001350162.2) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as rs753475065, COSV56344726; called by muse, mutect2, varscan2
- ZNF185 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as rs1556878902, COSV59274434; called by mutect2, varscan2
- ZNF831 | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV100926238; called by mutect2, varscan2
- CACNA1E | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CHD6 | c.3242G>T p.R1081I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- COL2A1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2
- KDR | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MYO7A | c.751A>T p.N251Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SUV39H1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC244197.3 | c.633C>T p.C211= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as CM128196; called by muse, mutect2, varscan2
- ADAMTS6 | c.2097T>C p.S699= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- ASTN2 | c.3465C>T p.I1155= (on ENST00000313400 / NM_001365069.1; = p.I1104= on NM_014010.5) | Silent (SNP) | VAF 39/127 reads (31%) | called by muse, mutect2, varscan2
- CDH7 | c.1953G>A p.V651= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV59896909; called by muse, mutect2, varscan2
- CENPF | c.6363C>T p.I2121= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs760713786; called by muse, mutect2, varscan2
- CLTC | c.1992A>G p.L664= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- FCGBP | c.1515C>T p.D505= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- HS3ST5 | c.225C>T p.N75= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs369975277; called by muse, mutect2, varscan2
- IGSF21 | c.699C>T p.D233= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs146733691; called by mutect2, varscan2
- KDM5B | c.3417T>A p.A1139= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- NEB | c.5976C>T p.L1992= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1433412595; called by muse, mutect2, varscan2
- NLRP11 | c.2817G>A p.E939= | Silent (SNP) | VAF 34/192 reads (18%) | called by mutect2, varscan2
- STIP1 | c.1320G>A p.A440= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs368536005; called by muse, mutect2, varscan2
- TENM3 | c.1299G>A p.R433= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101304958; called by muse, mutect2, varscan2
- ZSWIM6 | c.2088G>A p.L696= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV53175514; called by muse, mutect2, varscan2
